TCGA case TCGA-CG-5716 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/49587564-e30f-4f1c-b7b3-fc0989bb1a0a

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 85 years; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.3; Tissue or organ of origin: Gastric antrum; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 86.0 years (31,411 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T4a; AJCC pathologic N: N2; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Days to last follow up: 0 days.
2. Prior malignancy of the prostate gland (histology not recorded by GDC).
   Treatment given: Treatment type: Hormone Therapy.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 0 days; Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CG-5716-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-CG-5716-01A-01-BS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-CG-5716-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CG-5716-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Anatomic organ subdivision: Antrum/Distal; Cancer procurement city: Hamburg.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Malignant neoplasm of prostate.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -2404.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy prostate cancer treated with chemotherapy and radiation.
- Prior malignancy: Prior malignancy prostate cancer treated with chemotherapy and radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 0 days; disease-specific survival: no event (censored), 0 days; progression-free interval: no event (censored), 0 days.
